Gene-level copy-number profile of tumor specimen TCGA-34-5236-01A from TCGA case TCGA-34-5236, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.1 years (21,935 days).
Specimen TCGA-34-5236-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.fcc8f20f-6b8d-40fc-b327-a0a633403b72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-5236-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4d42c08-c6c8-42db-a258-fbcea421a70b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,736; copy number 2: 8,220; copy number 3: 27,015; copy number 4: 10,060; copy number 5: 4,744; copy number 6: 4,542; copy number 7: 1,119; copy number 8: 476; copy number 9: 62; copy number 10: 646; copy number 11: 119; copy number 13: 42; copy number 15: 17; copy number 18: 9; copy number 20: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-5236-01A-21D-1816-01): tumor purity 0.18, ploidy 4.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,494 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,026,498–206,946,466, 130 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:210,231,456–210,676,296, 9 genes, copy number 7 (within-gene range 5–7): SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P.
- chr2:117,023,918–117,804,174, 7 genes, copy number 7: MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1.
- chr3:161,816,909–198,222,513, 646 genes, copy number 10 (broad region; genes not listed).
- chr5:16,067,139–16,936,288, 14 genes, copy number 9 (within-gene range 6–9): MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28.
- chr5:43,376,645–45,895,970, 30 genes, copy number 8: CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:70,972–15,562,015, 259 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:45,574,140–56,409,210, 168 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:68,020,235–110,592,204, 770 genes, copy number 7–9 (broad region; genes not listed).
- chr8:76,162,119–76,683,308, 8 genes, copy number 18: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1.
- chr8:76,733,302–76,733,476, 1 gene, copy number 18: AC011716.1.
- chr11:92,336,032–97,259,987, 110 genes, copy number 8–11 (broad region; genes not listed).
- chr18:26,016,253–37,762,131, 167 genes, copy number 8–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:46,667,821–50,195,147, 83 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr19:13,862,063–15,498,956, 87 genes, copy number 8–15 (within-gene range 2–15) (broad region; genes not listed).
- chr19:15,515,342–15,516,836, 1 gene, copy number 15: AC011492.1.
- chr21:19,593,841–19,760,128, 4 genes, copy number 20: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1.

Autosomal genes at a single copy (total copy number 1): 2,526. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
